Gene-level copy-number profile of tumor specimen TCGA-AN-A0FD-01A from TCGA case TCGA-AN-A0FD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.2 years (26,007 days).
Specimen TCGA-AN-A0FD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.ba8ff683-777a-4d41-9261-014c89e17791.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0FD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ef4250f1-e6cb-43c3-b15e-bca4a2cf26d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 14,931; copy number 2: 43,710; copy number 3: 577; copy number 4: 248; copy number 5: 185; copy number 6: 39; copy number 9: 121.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0FD-01A-11D-A036-01): tumor purity 0.76, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 345 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:49,289,206–49,574,064, 14 genes, copy number 5 (within-gene range 3–5): ZNF652, AC091180.2, AC091180.5, AC091180.4, AC091180.1, PHB, AC091180.3, Y_RNA, EIF4EP2, LINC02075, AC015656.1, NGFR, AC006487.1, MIR6165.
- chr17:53,105,734–53,106,358, 1 gene, copy number 6: MTCO1P40.
- chr17:53,353,427–53,354,134, 1 gene, copy number 6: AC005341.1.
- chr17:54,477,796–54,478,168, 1 gene, copy number 5: ISCA1P3.
- chr17:55,264,960–56,595,611, 16 genes, copy number 6: HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1, AC006600.2, RPL39P33, NOG.
- chr17:57,971,547–60,666,280, 117 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr17:60,696,313–60,811,462, 4 genes, copy number 9: RN7SL606P, AC110602.1, Y_RNA, KRT18P61.
- chr17:61,865,367–63,005,152, 38 genes, copy number 5: INTS2, Y_RNA, MED13, AC018628.1, RN7SL800P, AC018628.2, Y_RNA, Y_RNA, POLRMTP1, AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1, EFCAB3, AC008026.2, RNU7-52P, RPS23P7, METTL2A, TLK2, AC008026.1, AC008026.3, AC080038.2, AC080038.1, MRC2, Y_RNA, AC080038.3, RNU6-446P, AC005821.1, MARCHF10, AC005821.2, MARCHF10-DT, PRELID3BP3, AC005972.3, MIR633, TRMT112P3, AC005972.1, AC005972.2.
- chr17:67,044,554–67,697,261, 18 genes, copy number 5 (within-gene range 2–5): CACNG1, HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1.
- chr17:72,645,949–73,092,712, 1 gene, copy number 6 (within-gene range 2–6): SLC39A11.
- chr17:72,839,039–73,911,878, 21 genes, copy number 5–6 (within-gene range 2–6): AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4, SDK2, AC124804.1, AC032019.1, AC032019.2, AC125421.1, LINC00469, LINC02092, AC125421.2, AC137735.1.
- chr19:15,159,038–16,066,312, 53 genes, copy number 5: NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1, CYP4F23P, AD000091.1, RPL23AP2, AC093072.1, CYP4F8, CYP4F3, CYP4F10P, CYP4F12, OR10H2, OR10H3, CYP4F24P, AC004597.1, OR10H5, OR10H1, ZNF861P, AC004510.2, LINC01764, UCA1, AC004510.1, CLEC4O, CYP4F36P, CYP4F2, AC005336.2, AC005336.3, AC005336.1, CYP4F11, OR10H4, CYP4F9P, LINC00661, AC004790.2, LINC00905, SNX33P1, AC004790.1, OR1AB1P, LINC01855.
- chr19:16,074,293–16,077,395, 1 gene, copy number 5: AC008894.3.
- chr19:17,468,769–18,544,077, 59 genes, copy number 5 (within-gene range 2–5): SLC27A1, AC010618.3, PGLS, AC010618.2, NIBAN3, COLGALT1, AC010618.1, UNC13A, AC008761.2, AC008761.3, MAP1S, AC008761.1, FCHO1, B3GNT3, INSL3, JAK3, RPL18A, SNORA68, AC005796.1, SLC5A5, CCDC124, KCNN1, RNA5SP468, ARRDC2, AC020904.3, AC020904.2, AC020904.1, RPS18P13, IL12RB1, MAST3, AC007192.2, AC007192.1, PIK3R2, IFI30, MPV17L2, RAB3A, AC005759.1, AC008397.2, PDE4C, AC008397.1, IQCN, JUND, MIR3188, RPL39P38, LSM4, RN7SL513P, PGPEP1, GDF15, MIR3189, LRRC25, SSBP4, ISYNA1, AC010335.1, ELL, AC010335.2, AC010335.3, AC005387.1, FKBP8, AC005387.2.

Autosomal genes at a single copy (total copy number 1): 12,902. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
